Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68C, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68C-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE -
NAME:

PATIENT NBR:

PAGE #: 1
SEX: M

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY

Recently found to have a pheochromocytoma. Lap vs open adrenalectomy right.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland." Received in formalin in a medium container is an adrenalectomy specimen (7.3 x 8 x 4.5 cm, 137.605 gm) with surrounding freely mobile soft tissue. Photos taken.

There is a well-encapsulated hemorrhagic heterogenous soft mass (7.5 x 6.3 x 2.5 cm) with focal fibrosis. There is a rim (5.7 x 0.6 cm) of remaining compressed adrenal gland.

Ink code:
Blue=soft tissue margin.

- 1A. mass with adjacent adrenal gland and margin.
- 1B. Mass with fibrous area and hemorrhage (no margin).
- 1C. Mass to margin.
- 1D. Mass to margin.
- 1E. Mass to margin.

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal gland, resection: Pheochromocytoma (7.5 cm). Margins negative.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

	Yes	No
Staging Discrepancy		/
Malignancy History		/
Synchronous Primary Tumor		/

hw 4/22/13

Source: NCI Genomic Data Commons file df320a0a-58f1-4a97-ac3b-da7a5053b8f4 (TCGA-RW-A68C.BE6F86BE-8C01-4A23-ADFE-1A248798E1DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).